Somatic mutation profile of tumor specimen 0DRCK1 from CCDI case PBCEWU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pinealoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,908 days).
Specimen 0DRCK1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d404cd99-097e-45f9-895f-1ecdfa35cb7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRCJV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb1fc0a8-8949-4d47-bf89-7b1d3382ef8a

The open-access MAF lists 15 somatic variants for this specimen: 6 protein-altering or splice-affecting, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 5, 3'UTR 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MS4A8 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 52/654 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs768046843, COSV55753951; called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 76/1798 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PRRC2A | c.4775C>T p.P1592L | Missense Mutation (SNP) | VAF 46/1368 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- SLCO1A2 | c.1787C>A p.T596N | Missense Mutation (SNP) | VAF 36/712 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- WDSUB1 | c.1218T>A p.D406E | Missense Mutation (SNP) | VAF 36/1451 reads (2%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 62/1307 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 48/1184 reads (4%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 22/234 reads (9%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 22/226 reads (10%) | called by muse, varscan2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 82/706 reads (12%) | called by muse, varscan2
- LRRC4 | c.-69C>G | 5'UTR (SNP) | VAF 25/247 reads (10%) | catalogued as rs1203560001; called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 12/73 reads (16%) | called by muse, varscan2
- MED23 | c.2779-34G>T | Intron (SNP) | VAF 24/426 reads (6%) | called by muse, mutect2
- PLGRKT | c.*95G>A | 3'UTR (SNP) | VAF 19/178 reads (11%) | called by muse, varscan2
